CCDI case PBBXMY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acinar Cell Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/bac7f975-74d5-4e6a-a6f5-2ac4af57d99a

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Acinar cell carcinoma: ICD-O-3 morphology code: 8550/3; Tissue or organ of origin: Tail of pancreas; Age at diagnosis: 11.1 years (4,059 days).

Biospecimens (3 samples)
- Sample 0DK0AB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK0AM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DK0AP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
